Gene-level copy-number profile of specimen HCM-CSHL-0507-C20-85A from HCMI case HCM-CSHL-0507-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 61.5 years (22,461 days).
Specimen HCM-CSHL-0507-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 33484a21-96b8-405d-90ae-3efb3fc77125.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0507-C20-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/6ad1de7e-73e6-40fa-8592-ddb00b3541a0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 315; copy number 1: 4; copy number 2: 9,338; copy number 3: 15,469; copy number 4: 29,050; copy number 5: 2,539; copy number 6: 1,337; copy number 7: 122; copy number 8: 743.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
